Somatic mutation profile of tumor specimen 0E0JS0 from CCDI case PBCUWR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0JS0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47d6b6ed-f6fd-4512-9f20-dd83cfedc181.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0JS5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e37e1c6-2d24-4d47-bbd6-988120241a76

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 4, In Frame Del 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.4001_4003del p.V1334del | In Frame Del (DEL) | VAF 98/297 reads (33%) | called by mutect2, varscan2
- CYP2U1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, varscan2
- DYNC2H1 | c.10719G>T p.L3573F | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, varscan2
- IL10RB | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- IQCH | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, varscan2
- SVEP1 | c.2259C>A p.C753* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- ACAT1 | c.334+12A>G | Intron (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- COA5 | c.100-31G>A | Intron (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- LRP3 | c.261-99G>T | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- NECAB3 | chr20:33674430 C>T | 5'Flank (SNP) | VAF 48/75 reads (64%) | called by muse, mutect2, varscan2
- UBA52 | c.103+53G>T | Intron (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
